Somatic mutation profile of tumor specimen 0DO2F8 from CCDI case PBCCEB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 14.2 years (5,190 days).
Specimen 0DO2F8: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1f50fab5-f0f8-40d5-b20a-91a4ef045ddf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DO2ES (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fabb7688-c8ba-47a0-91ed-ee6ec68ef3d8

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DICER1 | c.5437G>C p.E1813Q | Missense Mutation (SNP) | VAF 470/720 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as CM160050, COSV58615431, COSV58617855; called by muse, mutect2, varscan2
- ATP6V1FNB | c.481C>T p.R161C | Missense Mutation (SNP) | VAF 258/919 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1277460131; called by muse, mutect2, varscan2
- IL5RA | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 558/932 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.44); catalogued as COSV56520707, COSV56521023, COSV99843229; called by muse, mutect2, varscan2
- MALRD1 | c.734G>A p.R245Q | Missense Mutation (SNP) | VAF 223/354 reads (63%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs569452539, COSV71047837; called by muse, mutect2, varscan2
- HECTD4 | c.11394G>C p.K3798N | Missense Mutation (SNP) | VAF 59/985 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.381); called by muse, mutect2
- NR3C1 | c.1137del p.T380Lfs*2 | Frame Shift Del (DEL) | VAF 373/761 reads (49%) | called by mutect2, pindel, varscan2
- PLOD3 | c.1319G>T p.R440L | Missense Mutation (SNP) | VAF 349/592 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPP2 | c.357C>T p.T119= | Silent (SNP) | VAF 105/240 reads (44%) | catalogued as rs779526667; called by muse, mutect2, varscan2
- AC002519.2 | chr16:31808606 C>A | 3'Flank (SNP) | VAF 248/815 reads (30%) | called by muse, mutect2, varscan2
